Somatic mutation profile of tumor specimen TCGA-A4-7828-01A (aliquot TCGA-A4-7828-01A-11D-2136-08) from TCGA case TCGA-A4-7828, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 74.3 years (27,122 days).
Specimen TCGA-A4-7828-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f35f6d2d-fc1c-4391-a6db-306b9237d56d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7828-10A (Blood Derived Normal), aliquot TCGA-A4-7828-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/845805a8-09ed-446c-8c03-7b9f166ce828

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 4, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP6AP1 | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.211); catalogued as COSV62340993, COSV62341047; called by muse, mutect2, varscan2
- CCDC57 | c.1856G>C p.S619T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV58935706; called by muse, mutect2, varscan2
- CCDC7 | c.1197+1G>T p.X399_splice | Splice Site (SNP) | VAF 3/45 reads (7%) | catalogued as COSV53230772; called by muse, mutect2
- CMYA5 | c.9841del p.E3281Kfs*28 | Frame Shift Del (DEL) | VAF 23/139 reads (17%) | catalogued as rs1561213928; called by mutect2, pindel, varscan2
- COCH | c.917A>C p.N306T (on ENST00000216361 / NM_001347720.1; = p.N241T on NM_004086.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.915); catalogued as COSV53551435; called by muse, mutect2, varscan2
- CPA6 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV52732816; called by muse, mutect2, varscan2
- DHRS9 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV59140265; called by muse, mutect2
- DOCK2 | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV56964682; called by muse, mutect2, varscan2
- EDRF1 | c.3443A>G p.N1148S (on ENST00000356792 / NM_001202438.2; = p.N1114S on NM_015608.2) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs199695348, COSV61764523; called by muse, mutect2, varscan2
- EPB41L3 | c.1828A>T p.N610Y | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV59457265; called by muse, mutect2, varscan2
- ISOC2 | c.382C>T p.Q128* (on ENST00000425675 / NM_001136201.2; = p.Q144* on NM_024710.3) | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV50034865; called by muse, mutect2, varscan2
- MBNL3 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0.346); catalogued as COSV63731091; called by muse, mutect2, varscan2
- MROH7 | c.179A>C p.D60A | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV59873598; called by muse, mutect2, varscan2
- PKD1L1 | c.1540A>T p.N514Y | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56968220; called by muse, mutect2, varscan2
- PTPRT | c.1115C>A p.P372Q | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.772); catalogued as COSV61957916, COSV61990404; called by muse, mutect2, varscan2
- SLC6A8 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 3/24 reads (13%) | catalogued as COSV53472498; called by muse, mutect2
- SLCO2B1 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.16); catalogued as COSV56936006; called by muse, mutect2, varscan2
- TMEM205 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV55792126; called by muse, mutect2, varscan2
- TRIM33 | c.2605C>T p.H869Y | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV61823321; called by muse, mutect2, varscan2
- VGF | c.1430A>T p.E477V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV50801476; called by muse, varscan2
- ZKSCAN5 | c.1883G>A p.S628N | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV58743176; called by muse, mutect2
- APOB | c.13373dup p.D4459Rfs*20 | Frame Shift Ins (INS) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- POLR2B | c.2480_2482del p.E827del | In Frame Del (DEL) | VAF 10/68 reads (15%) | called by pindel, varscan2
- RTL9 | c.1211del p.R404Kfs*3 | Frame Shift Del (DEL) | VAF 156/593 reads (26%) | called by mutect2, pindel*, varscan2
- SPAG9 | c.3008_3009del p.I1003Tfs*16 (on ENST00000262013 / NM_001130528.3; = p.I989Tfs*16 on NM_003971.6) | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2965_2974del p.N989Cfs*4 | Frame Shift Del (DEL) | VAF 16/135 reads (12%) | called by mutect2, pindel
- ZNF488 | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- EPX | c.1998G>A p.L666= | Silent (SNP) | VAF 32/105 reads (30%) | catalogued as rs1408011271, COSV56596989; called by muse, mutect2, varscan2
- GTSF1 | c.129T>C p.D43= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV59938875; called by muse, mutect2, varscan2
- ITGA2 | c.2214C>G p.P738= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs142557473, COSV56861303, COSV99670329; called by muse, mutect2, varscan2
- PCDHAC1 | c.1236A>G p.Q412= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs782708968, COSV53855513; called by muse, mutect2, varscan2
- MROH1 | c.1142-7522C>T | Intron (SNP) | VAF 21/111 reads (19%) | catalogued as rs768407136, COSV58188446; called by muse, mutect2, varscan2
